Gene-level copy-number profile of tumor specimen C3N-02152-04 from CPTAC case C3N-02152, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.7 years (22,161 days).
Specimen C3N-02152-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a0bb5e3-8571-4a32-8041-1c2ef19b0286.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02152-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/f93bd399-ecf0-42ea-981c-cdb7989de301

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 503; copy number 1: 20,743; copy number 2: 33,440; copy number 3: 3,021; copy number 4: 775; copy number 5: 380; copy number 6: 52; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–2): IGKV2D-14.
- chr6:55,680,642–55,681,021, 1 gene: AL590290.1.
- chr17:16,137,768–16,137,872, 1 gene (within-gene range 0–1): RNU6-862P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 433 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:95,297,676–109,660,802, 358 genes, copy number 5 (broad region; genes not listed).
- chr11:135,061,781–135,075,908, 1 gene, copy number 7: LINC02684.
- chr12:5,948,877–6,866,632, 54 genes, copy number 5–6: VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P, AC125494.3, COPS7A, AC125494.2, MLF2, PTMS, LAG3, RN7SL380P, CD4, GPR162, P3H3, GNB3, CDCA3, USP5.
- chr12:32,985,838–34,249,958, 20 genes, copy number 5: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.

Autosomal genes at a single copy (total copy number 1): 19,868. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
